Somatic mutation profile of tumor specimen TARGET-20-PASBST-09A (aliquot TARGET-20-PASBST-09A-01D) from TARGET case TARGET-20-PASBST, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 22.8 years (8,315 days).
Specimen TARGET-20-PASBST-09A: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6a1ea05a-f104-4a33-aac2-f2aceaa635e6.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PASBST-14A (Bone Marrow Normal), aliquot TARGET-20-PASBST-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e673a57d-5a04-4486-87d6-957eeec2b1ce

The open-access MAF lists 4 somatic variants for this specimen: 4 protein-altering or splice-affecting.
By variant classification: Frame Shift Ins 3, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KIT | c.2447A>T p.D816V | Missense Mutation (SNP) | VAF 44/159 reads (28%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs121913507, CM952169, COSV55386424, COSV55388612, COSV55408930; ClinVar: other / uncertain significance / likely pathogenic / pathogenic; called by muse, varscan2
- CEBPA | c.961_962insTTCT p.N321Ifs*3 | Frame Shift Ins (INS) | VAF 22/95 reads (23%) | catalogued as COSV57196064; called by mutect2, pindel, varscan2
- CSF3R | c.2299dup p.Y767Lfs*5 | Frame Shift Ins (INS) | VAF 32/86 reads (37%) | called by mutect2, varscan2
- CSF3R | c.2298delinsTT p.Y767Lfs*5 | Frame Shift Ins (INS) | VAF 35/119 reads (29%) | called by mutect2*, pindel, varscan2*
